Gene-level copy-number profile of tumor specimen C3L-03491-54 from CPTAC case C3L-03491, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 55.9 years (20,405 days).
Specimen C3L-03491-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a75aeae-3b57-41e6-96a3-a331122c6a38.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03491-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,732 have no estimate.
https://portal.gdc.cancer.gov/files/9e446056-ebdc-4e93-8c5a-5ce14da7dbab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,110; copy number 1: 6,309; copy number 2: 42,936; copy number 3: 4,709; copy number 4: 958; copy number 5: 688; copy number 6: 458; copy number 7: 280; copy number 8: 181; copy number 9: 63; copy number 10: 41; copy number 11: 34; copy number 12: 25; copy number 13: 22; copy number 14: 23; copy number 15: 10; copy number 16: 4; copy number 17: 6; copy number 18: 4; copy number 20: 3; copy number 21: 2; copy number 22: 3; copy number 24: 1; copy number 25: 1; copy number 27: 2; copy number 28: 1; copy number 32: 1; copy number 37: 1; copy number 38: 1; copy number 39: 1; copy number 41: 2; copy number 43: 1; copy number 46: 1; copy number 55: 1; copy number 56: 1; copy number 76: 1; copy number 176: 3; copy number 230: 1; copy number 285: 1; copy number 341: 1.

Homozygous deletions (total copy number 0; autosomes only): 976 genes in 543 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,843,812–11,848,345, 4 genes: AL021155.2, AL021155.3, NPPA, AL021155.1.
- chr1:55,217,645–55,368,774, 4 genes: MIR4422HG, GYG1P3, MIR4422, GOT2P1.
- chr1:169,662,007–169,854,080, 5 genes (within-gene range 0–3): C1orf112, SELL, SELE, AL021940.1, METTL18.
- chr2:178,451,346–178,830,802, 14 genes (within-gene range 0–2): PJVK, NUDCP2, FKBP7, PLEKHA3, TTN-AS1, TTN, AC009948.2, AC009948.1, AC009948.3, AC010680.3, AC010680.2, AC010680.4, AC010680.5, AC010680.1.
- chr2:218,633,329–218,702,716, 4 genes (within-gene range 0–2): ZNF142, BCS1L, RNF25, STK36.
- chr2:219,229,783–219,278,170, 5 genes: ANKZF1, GLB1L, STK16, TUBA4A, TUBA4B.
- chr3:169,764,520–169,772,043, 4 genes: TERC, Telomerase-vert, ACTRT3, AC078802.1.
- chr4:47,490,967–47,914,667, 6 genes (within-gene range 0–4): AC107398.1, AC107398.2, AC092597.1, AC107068.2, AC107068.1, NFXL1.
- chr5:17,353,695–17,387,310, 4 genes: FTH1P10, AC026785.2, AC026785.3, LINC02111.
- chr5:139,273,752–139,333,365, 7 genes (within-gene range 0–6): MATR3, SNHG4, SNORA74D, SNORA74A, MATR3, RNA5SP195, RN7SKP64.
- chr6:26,277,609–26,432,383, 6 genes: H4C8, H3C9P, BTN3A2, BTN2A2, BTN3A1, BTN2A3P.
- chr6:29,329,626–29,457,071, 8 genes (within-gene range 0–3): DDX6P1, OR5V1, OR12D3, OR12D2, OR12D1, OR11A1, OR10C1, AL645927.1.
- chr6:33,314,406–33,366,243, 5 genes: ZBTB22, DAXX, SMIM40, SMIM40, LYPLA2P1.
- chr6:33,410,399–33,457,544, 6 genes (within-gene range 0–3): PHF1, CUTA, SYNGAP1, SYNGAP1-AS1, MIR5004, ZBTB9.
- chr7:64,794,388–64,864,370, 5 genes: ZNF138, AC073349.4, AC073349.2, SEPHS1P1, EEF1DP4.
- chr8:30,063,003–30,177,208, 6 genes (within-gene range 0–1): SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2.
- chr8:76,603,240–77,014,028, 7 genes (within-gene range 0–2): MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18.
- chr9:87,810,642–87,888,903, 8 genes (within-gene range 0–5): FBP2P1, ELF2P3, NPAP1P7, CTSLP8, AL772337.2, AL772337.1, AL772337.3, SPATA31E1.
- chr9:112,217,716–112,333,664, 5 genes (within-gene range 0–5): PTBP3, RN7SL57P, RNA5SP295, RN7SL430P, HSPE1P28.
- chr10:27,343,436–27,542,239, 5 genes: LINC02673, FAM210CP, TRIAP1P1, PTCHD3, RAB18.
- chr11:49,817,778–49,846,533, 4 genes: AC130364.1, AC130364.2, TRIM51FP, AP006587.5.
- chr11:62,662,817–62,679,117, 6 genes (within-gene range 0–2): C11orf98, LBHD1, CSKMT, SNORA57, UQCC3, UBXN1.
- chr11:62,690,275–62,754,184, 6 genes: BSCL2, HNRNPUL2-BSCL2, GNG3, HNRNPUL2, TTC9C, ZBTB3.
- chr11:62,787,402–62,834,043, 9 genes (within-gene range 0–2): TMEM179B, MIR6748, NXF1, MIR6514, STX5, AP001160.4, RNU6-118P, AP001160.1, TEX54.
- chr11:77,717,712–77,813,676, 4 genes (within-gene range 0–2): RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1.
- chr11:112,025,408–112,086,798, 7 genes (within-gene range 0–4): DLAT, PPIHP1, RNU6-893P, AP000907.3, PIH1D2, NKAPD1, TIMM8B.
- chr11:118,994,824–119,018,691, 6 genes (within-gene range 0–1): CENATAC-DT, CENATAC, RPL23AP64, AP003392.1, AP003392.2, RPS25.
- chr12:2,695,765–2,812,902, 4 genes (within-gene range 0–7): ITFG2-AS1, LINC02371, IQSEC3P1, AC092471.1.
- chr15:34,225,013–34,367,196, 7 genes (within-gene range 0–1): EMC4, SLC12A6, AC079203.2, Y_RNA, NOP10, NUTM1, LPCAT4.
- chr15:42,581,156–42,737,128, 4 genes (within-gene range 0–3): EIF4EBP2P2, CDAN1, AC090510.3, AC090510.2.
- chr15:69,391,192–69,448,427, 5 genes (within-gene range 0–4): AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1.
- chr16:8,847,650–8,869,012, 4 genes (within-gene range 0–3): AC012173.1, AC022167.2, CARHSP1, AC022167.1.
- chr16:89,490,719–89,564,542, 4 genes (within-gene range 0–330): SPG7, AC092123.1, RPL13, SNORD68.
- chr17:10,320,392–10,623,886, 8 genes (within-gene range 0–7): AC005291.1, AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1.
- chr17:42,561,467–42,578,366, 4 genes (within-gene range 0–2): COASY, MLX, PSMC3IP, AC067852.5.
- chr17:60,079,309–60,136,271, 7 genes (within-gene range 0–8): AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7.
- chr17:64,940,602–64,956,546, 5 genes: AC037487.4, AC103810.8, AC037487.1, AC037487.3, SLC16A6P1.
- chr17:75,827,225–75,896,951, 5 genes: UNC13D, WBP2, TRIM47, AC087289.5, TRIM65.
- chr19:49,487,510–49,493,057, 5 genes (within-gene range 0–2): RPL13A, SNORD32A, SNORD33, SNORD34, SNORD35A.
- chr20:33,657,087–33,674,463, 4 genes: NECAB3, C20orf144, ACTL10, ACTL10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,725 genes in 756 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,654,609–5,668,295, 7 genes, copy number 5–14: AJAP1, Z98886.1, LINC02782, Z98259.3, Z98259.1, AL365255.1, Z97988.1.
- chr1:201,622,885–201,829,559, 7 genes, copy number 6 (within-gene range 1–13): NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231.
- chr2:2,319,232–3,157,797, 8 genes, copy number 5–15: MYT1L-AS1, AC018685.2, AC011995.2, AC018685.1, AC011995.1, LINC01250, AC019118.2, AC019118.1.
- chr2:29,192,774–30,143,804, 7 genes, copy number 6 (within-gene range 3–8): ALK, AC074096.1, RN7SL516P, AC106870.3, AC106870.2, AC106870.1, AC016907.2.
- chr2:30,187,434–30,408,346, 6 genes, copy number 5–8: SNORA10B, H3P5, LBH, AC109642.1, LINC01936, AC073255.1.
- chr2:139,732,708–140,221,485, 7 genes, copy number 5–8: RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:202,614,214–202,769,757, 9 genes, copy number 5: MTCO1P17, MTCO2P17, MTATP6P17, MTCO3P17, MTND3P17, MTND4LP17, MTND4P30, MTCO1P54, FAM117B.
- chr2:218,841,599–218,961,903, 6 genes, copy number 5–9 (within-gene range 0–9): RPL23AP31, WNT6, WNT10A, LINC01494, RNU6-642P, AC097468.2.
- chr3:187,796,187–188,154,057, 7 genes, copy number 5–7: AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2.
- chr4:14,164,455–14,888,169, 7 genes, copy number 5–8: AC092546.1, AC006296.3, AC006296.2, AC006296.1, LINC00504, MTND2P31, SNORA63.
- chr5:17,495,658–17,649,643, 25 genes, copy number 5–7: AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5.
- chr5:18,886,622–19,142,346, 7 genes, copy number 5–6: UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14.
- chr7:116,209,234–116,508,541, 7 genes, copy number 5–11 (within-gene range 4–11): AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP.
- chr7:130,822,868–130,939,661, 9 genes, copy number 5–8 (within-gene range 4–8): AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1.
- chr8:128,220,504–129,484,142, 7 genes, copy number 5–6: RN7SKP226, LINC00824, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr8:134,764,809–134,842,637, 7 genes, copy number 6–10: AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250.
- chr9:89,639,814–90,158,646, 9 genes, copy number 6–10: UNQ6494, BX470209.2, BX470209.1, AL161629.1, MIR4290HG, MIR4290, IL6RP1, AL161629.2, AL353649.1.
- chr9:129,332,300–129,584,556, 8 genes, copy number 6–12: LINC01503, AL353803.3, AL353803.2, AL353803.1, LINC00963, AL353803.4, AL391056.2, AL391056.1.
- chr9:134,293,931–134,553,897, 7 genes, copy number 5–17 (within-gene range 5–32): LINC02247, AL354796.1, RXRA, MIR4669, AL669970.1, AL669970.3, AL669970.2.
- chr10:78,352,597–79,316,528, 7 genes, copy number 6–14: AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1.
- chr11:69,371,463–69,654,474, 7 genes, copy number 5–10 (within-gene range 4–10): AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1.
- chr11:78,015,715–78,079,865, 6 genes, copy number 5 (within-gene range 2–9): AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2.
- chr12:130,121,925–130,266,725, 7 genes, copy number 6–341: AC026336.4, AC026336.3, FZD10-AS1, AC026336.5, FZD10, AC026336.1, AC026336.2.
- chr12:131,292,068–131,668,246, 19 genes, copy number 6–27: RPS6P20, AC092850.1, LINC02415, RNA5SP376, LINC02370, AC140118.2, AC140118.1, AC073578.4, AC073578.2, AC073578.1, AC073578.3, AC140063.1, AC117500.5, AC117500.3, LINC02414, AC117500.4, RNA5SP377, AC117500.1, RPS6P21.
- chr13:26,222,191–26,698,804, 9 genes, copy number 5–10 (within-gene range 2–27): AL138966.2, AL138966.1, THAP12P6, CDK8, AL159159.1, WASF3, RPS3AP44, WASF3-AS1, AL159978.1.
- chr13:43,908,669–44,397,714, 11 genes, copy number 5–8 (within-gene range 0–8): NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1, AL138960.1, SERP2.
- chr13:48,771,128–49,209,779, 6 genes, copy number 5–7 (within-gene range 0–7): PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2.
- chr14:102,932,380–103,279,955, 15 genes, copy number 5 (within-gene range 1–7): CDC42BPB, AL117209.1, RPL13P6, AL161669.1, EXOC3L4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12, GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13, RAP2CP1.
- chr15:33,985,406–34,210,096, 6 genes, copy number 5–6 (within-gene range 5–7): AC009268.3, AC009268.1, EMC7, AC079203.1, PGBD4, KATNBL1.
- chr16:50,100,339–50,318,135, 6 genes, copy number 5–7 (within-gene range 0–7): AC007610.2, AC007610.5, RPL10P14, SNORA70, TENT4B, ADCY7.
- chr17:61,034,636–61,400,243, 7 genes, copy number 5 (within-gene range 0–7): AC005884.1, AC005884.2, RPL23AP74, AC005856.1, AC005746.3, AC005746.2, AC005746.1.
- chr17:67,471,489–67,659,465, 6 genes, copy number 5 (within-gene range 5–7): MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3.
- chr18:70,489,630–71,033,056, 6 genes, copy number 5–10: AC091305.1, AC091646.1, RN7SL795P, GTSCR1, AC090415.2, AC090415.1.
- chr18:76,209,422–76,495,242, 7 genes, copy number 5–8 (within-gene range 1–8): LINC01893, AC103808.2, AC103808.4, AC103808.3, AC103808.1, AC103808.5, ZNF516.
- chr18:76,528,652–76,972,901, 10 genes, copy number 5–8 (within-gene range 0–9): LINC00683, AC034110.1, LINC01927, LINC01879, ARL2BPP1, AC139085.1, ZNF236-DT, RNU6-346P, AC027575.2, ZNF236.
- chr18:76,978,827–77,235,430, 7 genes, copy number 6–9 (within-gene range 0–13): MBP, AC093330.2, AC093330.3, AC018529.1, AC018529.3, AC018529.2, AC100863.1.
- chr19:28,316,705–28,727,777, 10 genes, copy number 6–8 (within-gene range 4–8): AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1.
- chr20:39,757,202–40,854,229, 7 genes, copy number 5–285: AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, AL035665.1, RNA5SP484.
- chr20:60,414,396–61,940,617, 13 genes, copy number 5–10 (within-gene range 5–17): MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2.
- chr22:27,676,559–28,008,581, 7 genes, copy number 5–8 (within-gene range 0–8): AL121885.2, AL121885.3, AL121885.1, MN1, PITPNB, TTC28-AS1, AL031591.2.

Autosomal genes at a single copy (total copy number 1): 6,127. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
